Surgical pathology report (de-identified scan), TCGA case TCGA-FX-A3TO, project TCGA-SARC (Sarcoma), tissue source site International Genomics Consortium, specimen TCGA-FX-A3TO-01A (Primary Tumor).

[page 1 of 3]
Patient Results

00:00

Surgical Pathology

Final

Path Report

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. :

Final Diagnosis(es):

(A) Soft tissue, retroperitoneal, rib, muscle and bone, excision:

1) Pleomorphic sarcoma, not otherwise specified (so called 'malignant fibrous histiocytoma').

2) Tumor size: 13.7 x 11.5 x 11.3 cm.

3) Necrosis: Present.

4) Margin status: Margins appear negative; A thin fibrous rim surrounds much of the lesion;

The tumor is, however, 1 mm or within 1 mm of anterior, lateral, inferior and medial margins.

5) Lymph-vascular invasion: Not identified.

6) Portion of rib uninvolved.

(B) Bone and soft tissue, rib, resection: Benign bone and soft tissue, negative for malignancy.

(C) Soft tissue, left psoas margin, excision: Benign fibroadipose tissue, negative for malignancy.

Comments:

This case has been reviewed and the diagnosis approved by consulting departmental surgical pathology staff.

A panel of immunostain is performed. Neoplastic cells are positive for vimentin. Scattered cells are positive for CD 68.

The is no appreciable staining for S-100, MAK-6, EMA, Desmin, Myogenin, Actin, Smooth Muscle Actin, Caldesmon. A CD 31 and 34 highlight benign vascular structures only. Stains performed at are: CDK4, MDM4, both are also negative.

'The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist'

Electronically Signed

Specimen(s) Received:

A: Left retroperitoneal mass, rib, and muscle

B: 12th rib

C: Left psoas margin

Clinical History:

Left retroperitoneal mass.

Gross Description:

(A) (left retroperitoneal mass, rib and muscle)

Specimen components and dimensions: Received fresh is an 850 gm intact resection containing soft tissue, rib, and skeletal muscle. The total specimen measures 15.5 cm medial to lateral,

IHPAA Discrepancy		X
Reviewed In	3/30/12	

ICD0-3

pleomorphic undifferentiated
Sarcoma 8830/3

Site: Retroperitoneum
C48.0

4-3-12 RO

Printed from: Default

Page: 1 of 4

[page 2 of 3]
Patient Results

12.5 cm anterior to posterior and 12.7 cm superior to inferior.

The portion of rib bone measures 9.0 x 1.2 x 0.5 cm. A portion of psoas muscle is present which measures 6.6 cm superior to inferior, 5.3 cm medial to lateral and 2.0 cm anterior to posterior. The specimen is inked in the following manner: Superior blue, inferior green, anterior yellow, medial red, lateral orange, posterior black.

Size, appearance, and location of tumor: The tumor measures 13.7 x 11.5 x approximately 11.3 cm. the rib bone is present at the posterosuperior margin and is mobile and does not appear to be directly invaded by the tumor. The tumor appears to be bound by a thin gray-pink fibrous capsule. On cut surface the tumor shows multilobulated gray-pink to yellow rubbery tissue with focal myxoid areas and approximately 5% necrosis. Grossly the tumor appears to infiltrate the skeletal muscle present along the posterior aspect.

Closest resection margins and distance: The tumor comes to within 0.1 cm of the anterior resection margin, 0.1 cm of the lateral resection margin. The tumor grossly appears to abut the medial resection margin, 0.3 cm to the superior margin, and 0.1 cm from the posterior margin.

Blocks submitted:

- A1 - anterior resection margin
- A2 - lateral resection margin
- A3 - inferior margin
- A4 - medial margin
- A5 - superior margin
- A6 - posterior margin
- A7 - tumor infiltrating muscle
- A8 - tumor to red bone

A9-A20 - additional representative sections of tumor
(B) (twelfth rib) Received in formalin is a segment of rib bone measuring 4.2 cm in length x 1.1 x 0.5 cm. A small amount of muscle and fatty tissue is attached to the rib which measures approximately 4.0 x 1.3 x 0.8 cm. Representative sections are submitted in B1 and B2 after decalcification.

(C) (left psoas margin) Received in formalin is a fibrofatty tissue fragment measuring 2.0 x 1.7 x 0.8 cm. One side of the specimen shows dark cautery artifact. The specimen is submitted intact in toto in cassette C1 en face to visualize the cauterized cut surface.

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents. These assays were developed and their performance characteristics determined by the

[page 3 of 3]
Patient Results

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26). Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file 5e1a9094-f2e2-43dd-af07-2879f3e37a16 (TCGA-FX-A3TO.4112C1D5-D510-45C7-A87B-1BEAB3DEFE65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).